Somatic mutation profile of tumor specimen 161317f3-1a39-438e-af45-cd2502 (aliquot 161317f3-1a39-438e-af45-cd2502_D6) from CPTAC case 04OV048, project CPTAC-2 (Other and unspecified female genital organs — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Fallopian tube; FIGO stage: Stage IIIC.
Specimen 161317f3-1a39-438e-af45-cd2502: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ce919bd-2a26-45d2-a140-288adbec7ffd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 61eae7d1-c81a-45c9-b8fa-017c02 (Blood Derived Normal), aliquot 61eae7d1-c81a-45c9-b8fa-017c02_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/daecf98e-38ac-4b30-b27f-2ec57372468e

The open-access MAF lists 69 somatic variants for this specimen: 44 protein-altering or splice-affecting, 20 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 20, Nonsense Mutation 4, In Frame Del 3, Intron 3, RNA 2, Splice Region 2, Splice Site 1, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 170/296 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AATK | c.3688_3690del p.K1230del (on ENST00000326724 / NM_001080395.3; = p.K1127del on NM_004920.2) | In Frame Del (DEL) | VAF 18/112 reads (16%) | catalogued as rs757851302; called by pindel, varscan2
- ANKRD11 | c.6535G>A p.V2179I | Missense Mutation (SNP) | VAF 79/215 reads (37%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV56354544; called by muse, mutect2, varscan2
- ATAD5 | c.2567C>T p.A856V | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs768638862; called by muse, mutect2, varscan2
- CACNA2D4 | c.1326G>T p.M442I | Missense Mutation (SNP) | VAF 57/378 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV99765322; called by muse, mutect2, varscan2
- FAM184B | c.2760_2763del p.E921Tfs*37 | Frame Shift Del (DEL) | VAF 51/233 reads (22%) | catalogued as rs778785791; called by mutect2, pindel, varscan2
- KRT75 | c.777C>T p.D259= | Splice Region (SNP) | VAF 50/284 reads (18%) | catalogued as rs373953042; called by muse, mutect2, varscan2
- KRTAP27-1 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 97/356 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs768941034; called by muse, mutect2, varscan2
- MEGF6 | c.3703C>T p.R1235C | Missense Mutation (SNP) | VAF 109/495 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.676); catalogued as rs773750025, COSV53895097; called by muse, mutect2, varscan2
- MEGF8 | c.5198G>A p.R1733H (on ENST00000251268 / NM_001271938.2; = p.R1666H on NM_001410.3) | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.03); catalogued as rs371976691; called by muse, mutect2, varscan2
- NPR1 | c.1718G>A p.R573H | Missense Mutation (SNP) | VAF 65/351 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as rs145787747, COSV64117934; called by muse, mutect2, varscan2
- NT5C | c.239C>A p.A80D | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs767244726; called by muse, mutect2, varscan2
- OR1D2 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 90/517 reads (17%) | catalogued as rs375718913; called by muse, mutect2, varscan2
- OR4X1 | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 92/454 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1401883657; called by muse, mutect2, varscan2
- PCNX3 | c.4255G>T p.E1419* | Nonsense Mutation (SNP) | VAF 72/512 reads (14%) | catalogued as COSV100856258; called by muse, mutect2, varscan2
- RABL2B | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 144/404 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.843); catalogued as rs782241181; called by muse, mutect2, varscan2
- RANBP10 | c.446C>A p.S149* | Nonsense Mutation (SNP) | VAF 52/135 reads (39%) | catalogued as COSV58160384, COSV58161287; called by muse, mutect2, varscan2
- RNF40 | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 44/244 reads (18%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.743); catalogued as rs751895980; called by muse, mutect2, varscan2
- SLC25A29 | c.778C>T p.P260S (on ENST00000359232 / NM_001039355.3; = p.P194S on NM_152333.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/251 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759833730; called by muse, mutect2, varscan2
- TENM2 | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 65/330 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.597); catalogued as COSV72855322; called by muse, mutect2, varscan2
- WDR49 | c.785G>A p.R262Q (on ENST00000308378 / NM_001366158.1; = p.R603Q on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs538758282, COSV100392863, COSV57718577; called by muse, mutect2, varscan2
- ZAN | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 158/258 reads (61%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.639); catalogued as rs1270048770; called by muse, mutect2, varscan2
- ARL6IP6 | c.20G>T p.G7V | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- BEGAIN | c.961T>G p.S321A | Missense Mutation (SNP) | VAF 152/614 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- C2CD5 | c.1461G>T p.R487S | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- CACNG3 | c.-2_35del | Translation Start Site (DEL) | VAF 51/254 reads (20%) | called by mutect2, pindel, varscan2
- CEP152 | c.1878T>A p.N626K | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- CNTNAP5 | c.3481T>C p.F1161L | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DICER1 | c.1117G>A p.V373I | Missense Mutation (SNP) | VAF 147/730 reads (20%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- DIXDC1 | c.1221G>C p.V407= (on ENST00000440460 / NM_001037954.4; = p.V196= on NM_033425.4) | Splice Region (SNP) | VAF 16/164 reads (10%) | called by muse, mutect2, varscan2
- ERICH3 | c.2225_2257del p.T742_A752del | In Frame Del (DEL) | VAF 24/144 reads (17%) | called by mutect2, pindel
- ITGA2B | c.738C>G p.H246Q | Missense Mutation (SNP) | VAF 163/644 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- KMT5B | c.1649A>T p.E550V | Missense Mutation (SNP) | VAF 76/318 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- MARCKS | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MYCBP2 | c.4413A>T p.L1471F (on ENST00000357337; = p.L1509F on NM_015057.5) | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- NLRP8 | c.667G>C p.V223L | Missense Mutation (SNP) | VAF 78/317 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- RFLNA | c.403A>T p.S135C (on ENST00000546355 / NM_001365156.1; = p.S54C on NM_181709.4) | Missense Mutation (SNP) | VAF 28/444 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- RTKN | c.545+2_545+19del p.X182_splice (on ENST00000272430 / NM_001015055.2; = p.X169_splice on NM_033046.2) | Splice Site (DEL) | VAF 36/214 reads (17%) | called by mutect2, pindel, varscan2
- SDR16C5 | c.874T>G p.Y292D | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- TCAF2 | c.2187C>A p.Y729* | Nonsense Mutation (SNP) | VAF 84/432 reads (19%) | called by muse, mutect2, varscan2
- TNR | c.3072_3116del p.N1025_T1039del | In Frame Del (DEL) | VAF 62/245 reads (25%) | called by mutect2, pindel
- UNC5B | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 63/207 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VARS2 | c.1324A>G p.I442V | Missense Mutation (SNP) | VAF 42/300 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- WDFY4 | c.6935C>T p.S2312L | Missense Mutation (SNP) | VAF 50/256 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACO2 | c.543T>C p.Y181= | Silent (SNP) | VAF 68/259 reads (26%) | called by muse, mutect2, varscan2
- BAZ1B | c.4356G>A p.R1452= | Silent (SNP) | VAF 51/328 reads (16%) | called by muse, mutect2, varscan2
- BTBD9 | c.1434G>A p.P478= | Silent (SNP) | VAF 15/173 reads (9%) | catalogued as rs181693343, COSV58422155; called by muse, mutect2
- EHD3 | c.1218C>T p.I406= | Silent (SNP) | VAF 28/310 reads (9%) | catalogued as COSV59030481; called by muse, mutect2
- FAM187A | c.66G>A p.E22= | Silent (SNP) | VAF 92/353 reads (26%) | catalogued as rs1242580045; called by muse, mutect2, varscan2
- GRM4 | c.1578G>A p.P526= | Silent (SNP) | VAF 78/383 reads (20%) | catalogued as rs145463048; called by muse, mutect2, varscan2
- KBTBD11 | c.1281C>T p.R427= | Silent (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2, varscan2
- LBP | c.534G>A p.L178= | Silent (SNP) | VAF 62/331 reads (19%) | called by muse, mutect2, varscan2
- LTBR | c.798G>A p.P266= | Silent (SNP) | VAF 68/310 reads (22%) | catalogued as rs536333390; called by muse, mutect2, varscan2
- MTA1 | c.603G>A p.A201= | Silent (SNP) | VAF 100/387 reads (26%) | catalogued as rs781860871, COSV58758319; called by muse, mutect2, varscan2
- MYO18A | c.3207C>T p.S1069= | Silent (SNP) | VAF 178/605 reads (29%) | called by muse, mutect2, varscan2
- NUPR2 | c.180C>T p.T60= | Silent (SNP) | VAF 51/180 reads (28%) | called by muse, mutect2, varscan2
- OPLAH | c.3678G>A p.T1226= | Silent (SNP) | VAF 39/275 reads (14%) | catalogued as rs372193469; called by muse, mutect2, varscan2
- POP1 | c.1947G>T p.V649= | Silent (SNP) | VAF 50/231 reads (22%) | called by muse, mutect2, varscan2
- PRDM8 | c.1968C>A p.P656= | Silent (SNP) | VAF 28/378 reads (7%) | called by muse, mutect2
- SERHL2 | c.168G>A p.P56= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as rs537393019; called by mutect2, varscan2
- SSPN | c.669C>T p.V223= | Silent (SNP) | VAF 79/411 reads (19%) | called by muse, mutect2, varscan2
- TMEM8B | c.918G>A p.V306= | Silent (SNP) | VAF 76/283 reads (27%) | catalogued as rs1347532925; called by muse, mutect2, varscan2
- TNPO2 | c.333C>T p.L111= | Silent (SNP) | VAF 12/236 reads (5%) | catalogued as rs1331329001; called by muse, mutect2
- TP53BP1 | c.3654T>C p.H1218= | Silent (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
- AC083864.1 | n.367G>T | RNA (SNP) | VAF 57/229 reads (25%) | called by muse, mutect2, varscan2
- NMT2 | c.110+13368G>A | Intron (SNP) | VAF 88/365 reads (24%) | catalogued as rs11259521; called by muse, mutect2, varscan2
- OR4N3P | n.301C>A | RNA (SNP) | VAF 44/240 reads (18%) | called by muse, mutect2, varscan2
- SPG7 | c.1915+9C>A | Intron (SNP) | VAF 98/286 reads (34%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+1880_1459+1891del | Intron (DEL) | VAF 50/260 reads (19%) | called by mutect2, pindel, varscan2
